Gene-level copy-number profile of tumor specimen TCGA-39-5028-01A from TCGA case TCGA-39-5028, project TCGA-LUSC (Lung Squamous Cell Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IIIA; Age at diagnosis: 75.9 years (27,707 days).
Specimen TCGA-39-5028-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-LUSC.a98c0fc9-a6e2-4e8d-8978-a9f1d0625ddc.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-39-5028-11A (solid tissue normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 805 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/751aba94-a981-4fd1-9632-b929ce8827c4

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 6,108; copy number 2: 34,799; copy number 3: 16,237; copy number 4: 2,119; copy number 5: 351; copy number 6: 78; copy number 7: 3; copy number 8: 42; copy number 9: 56; copy number 28: 25.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-39-5028-01A-01D-1439-01): tumor purity 0.19, ploidy 3.3, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 555 genes in 9 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:25,227,855–29,955,405, 127 genes, copy number 5 (within-gene range 2–5) (broad region; genes not listed).
- chr2:38,861,720–43,882,988, 73 genes, copy number 6 (broad region; genes not listed).
- chr2:43,892,690–43,904,693, 2 genes, copy number 6: RNU6-1048P, RN7SL455P.
- chr6:99,424,922–108,030,718, 92 genes, copy number 5–9 (broad region; genes not listed).
- chr8:38,269,704–39,284,917, 25 genes, copy number 28 (within-gene range 1–28): NSD3, AC087362.2, AC087362.1, AC087623.2, LETM2, FGFR1, AC087623.3, AC087623.1, RPS20P22, C8orf86, AC069120.1, RNF5P1, AC016813.1, TACC1, Y_RNA, AC067817.1, AC067817.2, PLEKHA2, AC108863.1, HTRA4, TM2D2, ADAM9, SNORD38D, ADAM32, RPL3P10.
- chr8:40,519,565–40,901,854, 3 genes, copy number 7: AC010857.1, ZMAT4, AC048387.1.
- chr12:2,269,776–2,457,392, 3 genes, copy number 6: CACNA1C-IT3, AC005293.1, AC005414.1.
- chr12:28,978,584–32,993,754, 101 genes, copy number 5 (broad region; genes not listed).
- chr22:19,291,969–21,624,034, 129 genes, copy number 5–8 (within-gene range 2–8) (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 5,195. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
